Surgical pathology report (de-identified scan), TCGA case TCGA-28-5211, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5211-01C (Primary Tumor).

[page 1 of 6]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

TCGA-28-5211

Location: [REDACTED]

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

B. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

C. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 80% of tumor necrosis
- 90% of tumor cellularity

D. BRAIN, RIGHT PARIETAL, NCI #2:

- Glioblastoma multiforme, WHO grade IV ✓
- 90% of tumor necrosis
- 90% of tumor cellularity

E. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 50% of tumor necrosis
- 90% of tumor cellularity

F. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 60% of tumor necrosis
- 90% of tumor cellularity

G. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 60% of tumor necrosis
- 90% of tumor cellularity

H. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #6:

- Glioblastoma multiforme, WHO grade IV
- 30% of tumor necrosis
- 90% of tumor cellularity

I. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

J. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY:

Patient Case(s): [REDACTED]

Copy For: [REDACTED]
Page 1 of 1

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 6]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the 20% result in this case suggests the possibility of a relatively diminished response to [REDACTED].

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED].

subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme [REDACTED].

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Brain tumor ✓

MICROSCOPIC FINDINGS:

As best revealed on part B and J the tumor is composed of a hypercellular proliferation of pleomorphic nuclei associated with mitotic figures. The tumor is extensively necrotic and contains blood vessels with endothelial proliferation. Some gemistocytic element is detected and there are also cells with perinuclear clearing, but those are rare. Sections on part I predominantly demonstrate cortex and white matter with minimal tumor load.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	B1	Up to 20%
PTEN	B1	Retained (1-2+)
pMAPK	B1	Up to 95% of tumor nuclei and cytoplasm is positive
Laminin beta 1 (8/411)	B1	Up-regulated (2-3+)
Laminin beta 2 (9/421)	B1	Focal down-regulation with paranuclear retention

[page 3 of 6]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

P53

B1

Up to 5% of tumor nuclei are weakly positive (1+)

GROSS:

A. RIGHT PARIETAL FROZEN SECTION

Labeled with the patient's name, labeled "right parietal FS", and received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is one portion of tan soft tissue that has previously been submitted for frozen section consultation that measures 0.5 x 0.3 x 0.1 cm. Entirely submitted.

A1. FSA remnant - 1

B. RIGHT PARIETAL

Labeled with the patient's name, labeled "right parietal", and received in formalin are two portions of tan soft tissues that measure in aggregate to 0.7 x 0.5 x 0.4 cm. The individual fragments range in size from 0.2 to 0.7 cm in greatest dimension. There are focal areas of hemorrhage on the cut surface. No other lesions are grossly identified. Entirely submitted.

B1. 3

C. RIGHT PARIETAL NCI #1 - STUDY

Labeled with the patient's name, labeled "right parietal NCI #1 - study", and received in formalin is a single portion of tan soft tissue that measures 0.3 x 0.3 x 0.1 cm. No lesions are grossly identified. Entirely submitted.

C1. 1

D. RIGHT PARIETAL NCI #2 - STUDY

Labeled with the patient's name, labeled "right parietal NCI #2 - study", and received in formalin are two portions of tan soft tissue that measure in aggregate to 0.5 x 0.3 x 0.1 cm. No lesions are grossly identified. Entirely submitted.

D1. 2

E. RIGHT PARIETAL NCI #3 - STUDY

Labeled with the patient's name, labeled "right parietal NCI #3 - study", and received in formalin is a single portion of tan soft tissue that measures 0.7 x 0.3 x 0.1 cm. No lesions are grossly identified. Entirely submitted.

E1. 1

F. RIGHT PARIETAL NCI #4 - STUDY

Labeled with the patient's name, labeled "right parietal NCI #4 - study", and received in formalin is a single fragment of tan soft tissue with focal areas of hemorrhage that measures 0.5 x 0.5 x 0.1 cm. No other lesions are grossly identified. Entirely submitted.

F1. 1

G. RIGHT PARIETAL NCI #5 - STUDY

Labeled with the patient's name, labeled "right parietal NCI #5 - study", and received in formalin are two fragments of tan soft tissue with focal areas of hemorrhage that measure 1.0 x 0.4 x 0.1 cm. The individual fragments range in size from 0.2 to 1.0 cm in greatest dimension. No other lesions are grossly identified.

G1. 2

H. RIGHT PARIETAL NCI #6

Labeled with the patient's name, labeled "right parietal NCI #6", and received in formalin is a single irregular portion of tan soft tissue with focal areas of hemorrhage that measures 0.8 x 0.6 x 0.1 cm. No other lesions are grossly identified. Entirely submitted.

H1. 1

[page 4 of 6]
PATIENT:

***** Addendum - Please See End of Report *****

ACCESSION #:

I. RIGHT PARIETAL LOBE

Labeled with the patient's name, labeled "right parietal lobe", and received in formalin is a single cerebriform portion of tan soft tissue that measures 3.9 x 2.0 x 1.7 cm. The deep most aspect portion of the tissue has a brown-tan soft and friable mass with a white-tan spongy underlying area. The brown-tan mass most likely represents hemorrhage but will be further evaluated by microscopic evaluation. The specimen is serially sectioned and the cut surface shows a white-tan to gray spongy outer cortex with underlying white matter and the more deeper surface shows soft friable red-tan to brown hemorrhagic area. No other lesions are grossly identified. Entirely submitted.

Ink key:

Blue: Deep resection margin.

Slide key:

I1-I4. Brain - 3, 2, 2, 2

J. RIGHT PARIETAL TUMOR

Labeled with the patient's name, labeled "right parietal tumor", and received in formalin are multiple irregular lobulated tan hemorrhagic soft tissue that measure in aggregate to 2.7 x 2.8 x 0.5 cm. Individual fragments range in size from less than 0.1 cm to 2.4 cm in greatest dimension. Sectioning through the tissue reveals a crumbly soft friable center with focal areas of hemorrhage and necrosis. No other lesions or masses are grossly identified. Specimen entirely submitted.

Slide key:

J1. Largest portion of tumor serially sectioned - multiple

J2. Remaining tumor fragments - multiple

Gross dictated by

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN AND TP):

A. RIGHT PARIETAL FROZEN SECTION AND TP'S:

- Glioblastoma multiforme

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed

[page 5 of 6]
PATIENT:

***** Addendum - Please See End of Report *****

ACCESSION #:

[page 6 of 6]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: B1

RESULTS: POSITIVE for EGFR Amplification (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies showed amplification of the EGFR gene with a 4.4 ratio of EGFR signals to the centromere signals in 85.0% of the nuclei examined.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $< 40\%$ of the cells.

References:

[REDACTED]

These FISH tests were developed and their performance characteristics determined by [REDACTED] as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED]. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file ca0df8c6-8741-4c36-afd1-f6cbd6d01389 (TCGA-28-5211.67615E78-229A-4923-956E-3E7E5E25BB15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).